Somatic mutation profile of tumor specimen TCGA-V5-A7RB-01A (aliquot TCGA-V5-A7RB-01A-11D-A351-09) from TCGA case TCGA-V5-A7RB, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower third of esophagus; Tumor grade: GX; Age at diagnosis: 59.3 years (21,654 days).
Specimen TCGA-V5-A7RB-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9ef4ef93-e66d-47f4-b233-0036fa150ff8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-V5-A7RB-10A (Blood Derived Normal), aliquot TCGA-V5-A7RB-10A-01D-A351-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/16e2ea9b-31d5-4d38-9874-5bdad9806b9a

The open-access MAF lists 232 somatic variants for this specimen: 178 protein-altering or splice-affecting, 48 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 158, Silent 48, Nonsense Mutation 8, Splice Site 4, Intron 3, RNA 3, In Frame Del 3, Frame Shift Del 3, Splice Region 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.1004A>C p.K335T | Missense Mutation (SNP) | VAF 20/100 reads (20%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV62688046, COSV62689047, COSV62695316; called by muse, varscan2
- TP53 | c.743G>A p.R248Q | Missense Mutation (SNP) | VAF 23/39 reads (59%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs11540652, CM920675, COSV52661091, COSV52661580, COSV52675468, COSV52802300; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ACTN4 | c.610C>T p.R204W | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs915950010; called by muse, mutect2, varscan2
- ADAMTS16 | c.617A>G p.K206R | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0.017); catalogued as rs1346337405, COSV56999005, COSV57003849; called by mutect2, varscan2
- ADAMTS16 | c.1939T>G p.F647V | Missense Mutation (SNP) | VAF 19/68 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.321); catalogued as rs1263265207, COSV57006323, COSV99939817; called by muse, mutect2, varscan2
- ADGRB2 | c.629G>A p.R210H | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT tolerated (0.1); PolyPhen benign (0.019); catalogued as rs762644990; called by muse, varscan2
- APOA5 | c.430G>A p.V144M | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.036); catalogued as rs751198486, COSV57063783; called by muse, mutect2, varscan2
- AR | c.1841C>G p.S614C | Missense Mutation (SNP) | VAF 38/64 reads (59%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as COSV65956652, COSV65959837; called by muse, mutect2, varscan2
- CACNA1A | c.2435C>T p.T812M | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.251); catalogued as rs748099275, COSV64208189; called by muse, mutect2, varscan2
- CD1A | c.975T>C p.C325= | Splice Region (SNP) | VAF 10/50 reads (20%) | catalogued as rs769928363; called by muse, mutect2, varscan2
- CFAP58 | c.673C>A p.L225I | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.527); catalogued as COSV57212182; called by muse, mutect2, varscan2
- CHAT | c.982G>T p.D328Y | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60335014; called by muse, mutect2, varscan2
- CYLC2 | c.782A>G p.K261R | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.383); catalogued as COSV66339072; called by muse, mutect2, varscan2
- DCX | c.227G>A p.R76H | Missense Mutation (SNP) | VAF 21/38 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as CM131049, COSV57566118; called by muse, mutect2, varscan2
- DKK3 | c.484G>T p.A162S | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.017); catalogued as COSV58869181; called by muse, mutect2, varscan2
- DOCK2 | c.3072+2T>C p.X1024_splice | Splice Site (SNP) | VAF 14/64 reads (22%) | catalogued as rs1038360768; called by muse, mutect2, varscan2
- DSEL | c.2763C>G p.I921M | Missense Mutation (SNP) | VAF 24/46 reads (52%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.724); catalogued as COSV59495672; called by muse, mutect2, varscan2
- FBN3 | c.6160G>A p.E2054K | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.708); catalogued as rs149936210; called by muse, mutect2, varscan2
- FBXW7 | c.1727C>T p.T576M (on ENST00000281708 / NM_001349798.2; = p.T496M on NM_018315.5) | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as rs1429385222; called by muse, mutect2, varscan2
- GAS7 | c.1162G>T p.D388Y (on ENST00000432992 / NM_201433.2; = p.D248Y on NM_003644.3) | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV60441025; called by muse, mutect2, varscan2
- GFRA3 | c.578G>A p.R193H | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.93); catalogued as rs1223473920; called by muse, mutect2, varscan2
- GIT2 | c.2275_2277del p.N759del (on ENST00000355312 / NM_057169.5; = p.N681del on NM_014776.5) | In Frame Del (DEL) | VAF 9/33 reads (27%) | catalogued as rs776196849; called by pindel, varscan2
- HEATR5B | c.304A>G p.K102E | Missense Mutation (SNP) | VAF 19/67 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1231855015; called by muse, mutect2, varscan2
- HMCN1 | c.11024G>A p.R3675K | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.982); catalogued as rs768898863; called by muse, mutect2, varscan2
- HOXC9 | c.697G>T p.E233* | Nonsense Mutation (SNP) | VAF 20/59 reads (34%) | catalogued as COSV57717306; called by muse, mutect2, varscan2
- IGHV4-34 | c.218G>T p.W73L | Missense Mutation (SNP) | VAF 34/97 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.292); catalogued as rs781110683; called by muse, mutect2, varscan2
- INTS11 | c.614C>T p.T205M | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs997507615; called by muse, mutect2, varscan2
- IRF4 | c.918G>C p.K306N | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.445); catalogued as COSV66705346; called by muse, mutect2, varscan2
- KHDRBS2 | c.76C>T p.R26C | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as COSV55431480; called by muse, mutect2, varscan2
- KMT2A | c.5443G>A p.E1815K | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT tolerated (0.1); PolyPhen benign (0.015); catalogued as COSV63286790; called by muse, mutect2, varscan2
- KRT15 | c.605G>A p.R202H | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.828); catalogued as rs200854917, COSV99562809; called by muse, mutect2, varscan2
- KRT24 | c.934A>G p.K312E | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT tolerated (0.56); PolyPhen benign (0.373); catalogued as rs1424485288; called by muse, mutect2, varscan2
- LATS1 | c.82C>T p.R28W | Missense Mutation (SNP) | VAF 21/45 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.451); catalogued as rs191160444; called by muse, mutect2, varscan2
- LILRA1 | c.1146C>A p.F382L | Missense Mutation (SNP) | VAF 9/123 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52183597; called by muse, mutect2
- LRP12 | c.31C>T p.P11S | Missense Mutation (SNP) | VAF 15/131 reads (11%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.007); catalogued as rs1407231110; called by muse, mutect2, varscan2
- LRRIQ1 | c.735G>C p.E245D | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT tolerated (0.42); PolyPhen benign (0.183); catalogued as COSV67813510; called by muse, mutect2, varscan2
- LTBP4 | c.148G>A p.V50I (on ENST00000308370 / NM_001042544.1; = p.A6= on NM_003573.2) | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0); catalogued as rs1245008042, COSV52581263; called by muse, mutect2, varscan2
- MAP3K19 | c.2843G>A p.G948D | Missense Mutation (SNP) | VAF 3/35 reads (9%) | SIFT tolerated (0.96); PolyPhen benign (0); catalogued as COSV59639246; called by muse, mutect2
- MFAP3 | c.760_762del p.E254del | In Frame Del (DEL) | VAF 15/43 reads (35%) | catalogued as rs749361751; called by pindel, varscan2
- MMD2 | c.407G>A p.R136H | Missense Mutation (SNP) | VAF 53/127 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.846); catalogued as rs772762565, COSV101286896; called by muse, mutect2, varscan2
- MYO1F | c.2189G>A p.R730Q | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs868521444; called by muse, mutect2, varscan2
- NINL | c.2489C>T p.P830L | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs748441660, COSV54004915; called by muse, mutect2, varscan2
- NPR1 | c.1264G>A p.V422I | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT tolerated (0.76); PolyPhen benign (0.015); catalogued as rs759308171; called by muse, mutect2, varscan2
- OR10K1 | c.266A>C p.K89T | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT tolerated (0.55); PolyPhen benign (0.354); catalogued as rs956731453, COSV56871114; called by muse, mutect2
- OR13C2 | c.598C>G p.L200V | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT tolerated (0.43); PolyPhen benign (0.009); catalogued as COSV73377627; called by muse, mutect2, varscan2
- PCDHB11 | c.1381C>G p.R461G | Missense Mutation (SNP) | VAF 39/142 reads (27%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.336); catalogued as COSV61310634, COSV61313865; called by muse, mutect2, varscan2
- PLCD3 | c.1909G>A p.V637I | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.19); PolyPhen benign (0.018); catalogued as rs777313442, COSV51962024; called by muse, mutect2, varscan2
- POLR2B | c.2590G>A p.D864N | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs553505190; called by muse, mutect2, varscan2
- PZP | c.4300A>G p.S1434G | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.124); catalogued as COSV54353742; called by muse, mutect2, varscan2
- REG3G | c.82G>C p.E28Q | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.047); catalogued as COSV55447692; called by muse, mutect2, varscan2
- REPIN1 | c.1471G>T p.D491Y | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.853); catalogued as COSV68292371; called by muse, mutect2, varscan2
- RNF11 | c.289C>T p.R97W | Missense Mutation (SNP) | VAF 34/106 reads (32%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.892); catalogued as rs141444156; called by muse, mutect2, varscan2
- RNF213 | c.8740G>A p.A2914T | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs187719193, COSV60398935; called by muse, mutect2, varscan2
- SDK1 | c.4379G>A p.W1460* | Nonsense Mutation (SNP) | VAF 11/71 reads (15%) | catalogued as COSV67366284; called by muse, mutect2, varscan2
- SEMA6D | c.2941T>G p.L981V (on ENST00000316364 / NM_153618.2; = p.L919V on NM_020858.2) | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT tolerated (0.89); PolyPhen benign (0.003); catalogued as rs758330754, COSV60373388, COSV60376846; called by muse, mutect2, varscan2
- SH2D3A | c.176A>G p.H59R | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs371836476; called by muse, mutect2, varscan2
- SLC29A4 | c.625del p.A209Rfs*3 | Frame Shift Del (DEL) | VAF 6/30 reads (20%) | catalogued as COSV51876140; called by mutect2, pindel, varscan2
- SLF1 | c.2248A>G p.T750A | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT tolerated (0.9); PolyPhen benign (0); catalogued as rs940546949; called by muse, mutect2, varscan2
- SLFN12 | c.26C>T p.T9M | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.848); catalogued as rs143225670; called by muse, mutect2, varscan2
- SPANXC | c.181A>G p.R61G | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.492); catalogued as COSV62842127; called by mutect2, varscan2
- STAT5B | c.880C>T p.R294C | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.975); catalogued as rs199982340; called by muse, mutect2, varscan2
- SVEP1 | c.6433C>T p.R2145W | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs201043549; called by muse, mutect2, varscan2
- SYT1 | c.173C>T p.P58L | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as rs1431810122, COSV54046323, COSV54055678; called by muse, mutect2, varscan2
- TENM2 | c.1356A>C p.E452D (on ENST00000518659 / NM_001122679.2; = p.E220D on NM_001080428.3) | Missense Mutation (SNP) | VAF 26/49 reads (53%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as rs1562110996, COSV69124301, COSV69136431; called by muse, mutect2, varscan2
- TESPA1 | c.1055A>C p.K352T (on ENST00000316577 / NM_001098815.3; = p.K214T on NM_014796.2 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.04); catalogued as rs1565841727, COSV57256973; called by muse, mutect2, varscan2
- TEX14 | c.701C>T p.P234L (on ENST00000240361 / NM_001201457.2; = p.P228L on NM_031272.5) | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.13); catalogued as rs780055346, COSV53611506; called by muse, mutect2, varscan2
- TRIM61 | c.103T>G p.F35V | Missense Mutation (SNP) | VAF 14/151 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); catalogued as COSV61417478; called by muse, mutect2
- TTN | c.83902C>T p.R27968* (on ENST00000591111; = p.R20544* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 7/27 reads (26%) | catalogued as COSV60347470; called by muse, mutect2, varscan2
- TTN | c.48357A>C p.E16119D (on ENST00000591111; = p.E8695D on NM_003319.4) | Missense Mutation (SNP) | VAF 10/32 reads (31%) | PolyPhen benign (0.074); catalogued as COSV59905709; called by muse, mutect2, varscan2
- TTN | c.9479A>G p.E3160G (on ENST00000591111; = p.E3114G on NM_003319.4) | Missense Mutation (SNP) | VAF 10/16 reads (63%) | PolyPhen probably damaging (0.997); catalogued as rs1234344822; called by muse, mutect2, varscan2
- UBQLN3 | c.1051G>A p.E351K | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.026); catalogued as rs201503283, COSV100293465; called by muse, mutect2, varscan2
- USP24 | c.1440G>C p.K480N | Missense Mutation (SNP) | VAF 13/80 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.043); catalogued as COSV53776615; called by muse, mutect2, varscan2
- VANGL1 | c.634C>T p.R212W | Missense Mutation (SNP) | VAF 15/86 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.817); catalogued as rs568821247, COSV59621450; called by muse, mutect2, varscan2
- VPS41 | c.436A>C p.T146P | Missense Mutation (SNP) | VAF 12/82 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.915); catalogued as rs35693565; called by muse, mutect2, varscan2
- ZFP37 | c.65C>T p.A22V | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); catalogued as COSV65289127; called by muse, mutect2, varscan2
- ZNF100 | c.389C>T p.A130V | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs111519833; called by muse, mutect2, varscan2
- ZNF461 | c.1532G>A p.S511N | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT tolerated (0.4); PolyPhen benign (0.007); catalogued as rs1381890342; called by muse, mutect2, varscan2
- ZNF479 | c.478C>T p.H160Y | Missense Mutation (SNP) | VAF 120/273 reads (44%) | SIFT tolerated (0.1); PolyPhen benign (0.006); catalogued as rs1183624164, COSV58636387; called by muse, mutect2, varscan2
- ACTB | c.1095del p.G366Afs*16 | Frame Shift Del (DEL) | VAF 73/182 reads (40%) | called by mutect2, pindel, varscan2
- AKAP9 | c.1375C>G p.Q459E | Missense Mutation (SNP) | VAF 26/58 reads (45%) | SIFT tolerated (0.86); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- AP5B1 | c.1898C>T p.P633L | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ATF7IP | c.2066A>C p.Y689S | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.64); called by muse, mutect2, varscan2
- ATP2B3 | c.3440T>G p.F1147C | Missense Mutation (SNP) | VAF 20/27 reads (74%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- AWAT1 | c.214T>G p.W72G | Missense Mutation (SNP) | VAF 38/60 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- BBOX1 | c.125A>G p.D42G | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT tolerated (0.38); PolyPhen benign (0.099); called by muse, mutect2, varscan2
- BNC1 | c.559G>C p.E187Q | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- BOD1 | c.128C>G p.S43W | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); called by muse, mutect2, varscan2
- BRD8 | c.3478G>C p.G1160R | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- C12orf66 | c.255C>G p.S85R | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT tolerated (0.39); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- CCDC54 | c.808G>A p.E270K | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT deleterious (0.05); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- CDH18 | c.302T>G p.F101C | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CELA1 | c.201-5_209del p.X67_splice | Splice Site (DEL) | VAF 6/29 reads (21%) | called by mutect2, pindel
- CEP170 | c.1372A>C p.T458P | Missense Mutation (SNP) | VAF 24/141 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.28); called by muse, mutect2, varscan2
- CFAP74 | c.1334C>G p.S445* | Nonsense Mutation (SNP) | VAF 23/153 reads (15%) | called by muse, mutect2, varscan2
- CHAMP1 | c.2129_2131del p.Y710del | In Frame Del (DEL) | VAF 19/64 reads (30%) | called by pindel, varscan2
- CHRNB1 | c.1483C>A p.P495T | Missense Mutation (SNP) | VAF 30/101 reads (30%) | SIFT tolerated (0.38); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- CNBD2 | c.303G>T p.E101D | Missense Mutation (SNP) | VAF 39/57 reads (68%) | SIFT tolerated (0.25); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- CNTN5 | c.995T>C p.I332T | Missense Mutation (SNP) | VAF 26/77 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CRISPLD1 | c.551A>C p.N184T | Missense Mutation (SNP) | VAF 24/55 reads (44%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- DHX37 | c.2702C>T p.A901V | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT tolerated (0.25); PolyPhen benign (0.248); called by muse, mutect2
- ELAVL2 | c.470T>G p.L157R | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ELK1 | c.239A>G p.K80R | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ENPP4 | c.281A>G p.Y94C | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- ERO1B | c.211C>A p.R71S | Missense Mutation (SNP) | VAF 49/206 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- EVC2 | c.1250G>T p.S417I | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.69); called by muse, mutect2, varscan2
- FAM120C | c.1360G>A p.V454M | Missense Mutation (SNP) | VAF 17/35 reads (49%) | SIFT tolerated (0.55); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- FAM50A | c.555G>C p.Q185H | Missense Mutation (SNP) | VAF 18/30 reads (60%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.9); called by muse, mutect2, varscan2
- FASTK | c.386C>T p.P129L | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.831); called by muse, varscan2
- FBN2 | c.4990G>T p.G1664* | Nonsense Mutation (SNP) | VAF 19/62 reads (31%) | called by muse, mutect2, varscan2
- GALNT14 | c.329T>G p.L110R | Missense Mutation (SNP) | VAF 24/46 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GDF1 | c.308G>A p.R103H | Missense Mutation (SNP) | VAF 7/12 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GGNBP2 | c.1028T>C p.V343A | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); called by muse, mutect2, varscan2
- GOLGA7 | c.112-1G>C p.X38_splice | Splice Site (SNP) | VAF 8/16 reads (50%) | called by muse, mutect2, varscan2
- GON4L | c.1224A>C p.R408S | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- GPC5 | c.1004A>C p.Q335P | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT tolerated (1); PolyPhen benign (0.001); called by mutect2, varscan2
- GRIK4 | c.389A>G p.Q130R | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.498); called by muse, mutect2, varscan2
- GYS2 | c.177G>A p.W59* | Nonsense Mutation (SNP) | VAF 18/53 reads (34%) | called by muse, mutect2, varscan2
- HEPH | c.1474G>T p.D492Y (on ENST00000343002; = p.D225Y on NM_014799.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 3/33 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.673); called by muse, mutect2
- HOOK1 | c.356G>A p.R119K | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.527); called by muse, mutect2, varscan2
- IVL | c.683A>G p.Q228R | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.843); called by muse, varscan2
- KCNA5 | c.1315T>G p.F439V | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- KCTD9 | c.1070G>C p.G357A | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.405); called by muse, mutect2, varscan2
- KIAA1217 | c.1430G>C p.R477T | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- KLKB1 | c.1709G>T p.G570V | Missense Mutation (SNP) | VAF 59/206 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KRT18 | c.754A>G p.I252V | Missense Mutation (SNP) | VAF 23/64 reads (36%) | SIFT tolerated (0.05); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- LMNB2 | c.874A>C p.S292R | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.715); called by muse, mutect2
- LMNTD2 | c.239G>A p.W80* | Nonsense Mutation (SNP) | VAF 18/47 reads (38%) | called by muse, mutect2, varscan2
- LRRIQ1 | c.3749A>G p.Y1250C | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT tolerated (0.18); PolyPhen benign (0); called by muse, mutect2, varscan2
- MADD | c.3988G>C p.D1330H | Missense Mutation (SNP) | VAF 30/81 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MAP1A | c.1959A>G p.I653M | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.861); called by muse, mutect2, varscan2
- MED15 | c.1669G>A p.E557K (on ENST00000263205 / NM_001003891.3; = p.E517K on NM_015889.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/33 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- MGAT5B | c.1072C>A p.P358T | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.866); called by muse, mutect2, varscan2
- MOXD1 | c.1032G>C p.W344C | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- MPHOSPH8 | c.710A>T p.D237V | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.927); called by muse, mutect2, varscan2
- MSI1 | c.202T>G p.F68V | Missense Mutation (SNP) | VAF 19/70 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- MTA1 | c.570C>G p.D190E | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT tolerated (0.61); PolyPhen benign (0.02); called by muse, varscan2
- NAV2 | c.5008T>A p.S1670T (on ENST00000396087 / NM_001244963.2; = p.S1614T on NM_145117.5) | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- NAV2 | c.5009C>A p.S1670Y (on ENST00000396087 / NM_001244963.2; = p.S1614Y on NM_145117.5) | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- NEGR1 | c.693A>C p.K231N | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.142); called by muse, mutect2, varscan2
- NKAPL | c.91C>T p.Q31* | Nonsense Mutation (SNP) | VAF 15/68 reads (22%) | called by muse, mutect2, varscan2
- NKD2 | c.169G>C p.G57R | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT tolerated (0.13); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- OR2C3 | c.950T>C p.L317P | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- OR5AS1 | c.214A>C p.S72R | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PAAF1 | c.193A>G p.K65E | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.624); called by muse, mutect2, varscan2
- PDE10A | c.461C>T p.P154L | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PEG3 | c.3737T>G p.L1246R | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.776); called by muse, mutect2, varscan2
- PHC1 | c.2159G>C p.G720A | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- PHKG1 | c.617G>A p.G206D | Missense Mutation (SNP) | VAF 7/73 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PLCE1 | c.5180G>A p.G1727D | Missense Mutation (SNP) | VAF 3/31 reads (10%) | SIFT tolerated (0.05); PolyPhen benign (0.216); called by muse, mutect2
- PLXND1 | c.2933A>C p.Y978S | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- PREX2 | c.2701T>C p.S901P | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.16); called by muse, mutect2, varscan2
- RGS3 | c.950C>T p.S317F (on ENST00000350696 / NM_001282923.2; = p.S205F on NM_017790.4) | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- RPS9 | c.568G>T p.D190Y | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- RTP3 | c.398T>C p.L133S | Missense Mutation (SNP) | VAF 25/80 reads (31%) | SIFT tolerated (0.78); PolyPhen benign (0.137); called by muse, mutect2, varscan2
- RTRAF | c.294A>T p.K98N | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- SCN5A | c.1325A>T p.K442M | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); called by muse, mutect2, varscan2
- SF3B1 | c.3337A>G p.T1113A | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT tolerated (0.51); PolyPhen benign (0.169); called by muse, mutect2, varscan2
- SLC37A3 | c.651del p.F217Lfs*37 | Frame Shift Del (DEL) | VAF 6/35 reads (17%) | called by mutect2, pindel, varscan2
- SNX29 | c.2188T>A p.F730I | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- SPANXB1 | c.199A>G p.R67G | Missense Mutation (SNP) | VAF 42/458 reads (9%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.221); called by muse, mutect2
- STX19 | c.295A>C p.K99Q | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- SYT1 | c.602A>T p.K201I | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.805); called by muse, mutect2, varscan2
- TBC1D1 | c.2963-2A>T p.X988_splice | Splice Site (SNP) | VAF 29/76 reads (38%) | called by muse, mutect2, varscan2
- TENM3 | c.5945T>C p.L1982P | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- TMED1 | c.427C>T p.P143S | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.1); called by muse, mutect2, varscan2
- TRDC | c.355C>A p.H119N | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT tolerated (0.62); PolyPhen benign (0.146); called by muse, mutect2, varscan2
- TRGC2 | c.429T>C p.D143= | Splice Region (SNP) | VAF 54/230 reads (23%) | called by muse, varscan2
- TSEN2 | c.867T>A p.N289K | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- TTN | c.45761G>A p.G15254D (on ENST00000591111; = p.G7830D on NM_003319.4) | Missense Mutation (SNP) | VAF 6/28 reads (21%) | PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- UBQLN3 | c.1333G>C p.V445L | Missense Mutation (SNP) | VAF 33/93 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- UNC5C | c.256A>G p.S86G | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- UTY | c.1812T>G p.N604K | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- VPS37D | c.494C>T p.A165V | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT tolerated (0.76); PolyPhen benign (0.071); called by muse, mutect2
- XKR4 | c.1210T>G p.F404V | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- XRN1 | c.3862G>T p.D1288Y | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.073); called by muse, mutect2, varscan2
- ZFHX4 | c.4056A>T p.K1352N | Missense Mutation (SNP) | VAF 34/96 reads (35%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ZNF142 | c.218T>G p.M73R | Missense Mutation (SNP) | VAF 21/72 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- ZNF224 | c.850G>C p.G284R | Missense Mutation (SNP) | VAF 7/92 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); called by muse, mutect2
- ADGRB1 | c.1989G>A p.S663= | Silent (SNP) | VAF 27/113 reads (24%) | catalogued as rs756186697; called by muse, mutect2, varscan2
- ANK3 | c.12630G>A p.E4210= (on ENST00000280772 / NM_001320874.2; = p.E834= on NM_001149.3) | Silent (SNP) | VAF 8/25 reads (32%) | catalogued as rs762965634; called by muse, mutect2, varscan2
- ANO4 | c.2517T>C p.S839= (on ENST00000392977 / NM_001286615.2; = p.S804= on NM_178826.4) | Silent (SNP) | VAF 17/63 reads (27%) | called by muse, mutect2, varscan2
- APC | c.1212C>A p.I404= | Silent (SNP) | VAF 13/44 reads (30%) | catalogued as COSV57327994; called by muse, mutect2, varscan2
- ATRNL1 | c.2148T>C p.C716= | Silent (SNP) | VAF 16/52 reads (31%) | called by muse, mutect2, varscan2
- BICC1 | c.1803G>A p.P601= | Silent (SNP) | VAF 23/79 reads (29%) | catalogued as rs767919738; called by muse, mutect2, varscan2
- CD1C | c.639C>G p.R213= | Silent (SNP) | VAF 9/21 reads (43%) | catalogued as COSV63807313; called by muse, mutect2, varscan2
- CELSR3 | c.3831G>A p.V1277= | Silent (SNP) | VAF 6/20 reads (30%) | called by mutect2, varscan2
- COL5A1 | c.4152T>G p.G1384= | Silent (SNP) | VAF 12/57 reads (21%) | called by muse, mutect2
- CTAGE1 | c.1690C>T p.L564= | Silent (SNP) | VAF 41/139 reads (29%) | catalogued as rs189335114, COSV66942789; called by muse, mutect2, varscan2
- DYNC2H1 | c.3036A>G p.K1012= | Silent (SNP) | VAF 72/267 reads (27%) | catalogued as rs1462508267; called by muse, varscan2
- EPB41L3 | c.87G>A p.A29= | Silent (SNP) | VAF 4/12 reads (33%) | catalogued as COSV100548125; called by muse, mutect2, varscan2
- GLYATL2 | c.216C>G p.T72= | Silent (SNP) | VAF 19/42 reads (45%) | catalogued as COSV99780493; called by muse, mutect2, varscan2
- GPR141 | c.852C>A p.V284= | Silent (SNP) | VAF 19/64 reads (30%) | catalogued as COSV57731817; called by muse, mutect2, varscan2
- GPR158 | c.1980G>C p.G660= | Silent (SNP) | VAF 5/28 reads (18%) | catalogued as rs761150864; called by muse, mutect2, varscan2
- GRID1 | c.1704C>T p.C568= | Silent (SNP) | VAF 3/43 reads (7%) | called by muse, mutect2
- INSYN2A | c.255C>T p.R85= | Silent (SNP) | VAF 8/56 reads (14%) | called by muse, mutect2, varscan2
- IRF2BPL | c.2334C>T p.G778= | Silent (SNP) | VAF 16/59 reads (27%) | catalogued as COSV53147186; called by muse, mutect2, varscan2
- MUC16 | c.13845T>G p.T4615= | Silent (SNP) | VAF 17/39 reads (44%) | called by muse, mutect2, varscan2
- NEK1 | c.1476A>T p.A492= | Silent (SNP) | VAF 4/62 reads (6%) | called by muse, mutect2
- NRAP | c.2865C>G p.L955= (on ENST00000359988 / NM_001322945.2; = p.L920= on NM_006175.4) | Silent (SNP) | VAF 8/36 reads (22%) | called by muse, mutect2, varscan2
- OCA2 | c.1824C>T p.I608= | Silent (SNP) | VAF 8/54 reads (15%) | called by muse, mutect2, varscan2
- OR52E6 | c.675T>C p.A225= | Silent (SNP) | VAF 5/32 reads (16%) | catalogued as rs921478012; called by muse, mutect2, varscan2
- OTOP3 | c.1293C>T p.L431= | Silent (SNP) | VAF 8/29 reads (28%) | catalogued as rs1467278184; called by muse, mutect2, varscan2
- PCDH18 | c.1704C>T p.D568= | Silent (SNP) | VAF 5/16 reads (31%) | catalogued as rs373847652; called by muse, mutect2, varscan2
- PCDHA7 | c.2142C>T p.T714= | Silent (SNP) | VAF 19/61 reads (31%) | catalogued as rs782794742; called by muse, mutect2, varscan2
- PLD5 | c.1087T>C p.L363= (on ENST00000442594; = p.L301= on NM_001195811.1 and 1 other RefSeq transcript) | Silent (SNP) | VAF 24/76 reads (32%) | catalogued as rs1416109158, COSV59165459, COSV59170478; called by muse, mutect2, varscan2
- PLEKHH3 | c.1332C>T p.N444= | Silent (SNP) | VAF 14/39 reads (36%) | catalogued as rs1567958131, COSV52218986; called by muse, mutect2, varscan2
- PRLHR | c.141C>T p.V47= | Silent (SNP) | VAF 30/66 reads (45%) | called by muse, mutect2, varscan2
- SCN1A | c.4707G>A p.V1569= (on ENST00000303395 / NM_001202435.3; = p.V1558= on NM_006920.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 16/53 reads (30%) | called by muse, mutect2, varscan2
- SF3B1 | c.3870T>C p.D1290= | Silent (SNP) | VAF 22/67 reads (33%) | called by muse, mutect2, varscan2
- SH3BP4 | c.945G>C p.V315= | Silent (SNP) | VAF 12/33 reads (36%) | called by muse, mutect2, varscan2
- SNRPD2 | c.210G>A p.V70= | Silent (SNP) | VAF 14/49 reads (29%) | catalogued as rs751917445; called by muse, mutect2, varscan2
- SOX5 | c.522A>G p.K174= | Silent (SNP) | VAF 14/37 reads (38%) | catalogued as COSV58624954; called by muse, mutect2, varscan2
- STOX2 | c.2013G>A p.V671= | Silent (SNP) | VAF 16/47 reads (34%) | called by muse, mutect2, varscan2
- SYTL2 | c.690C>T p.I230= | Silent (SNP) | VAF 17/42 reads (40%) | catalogued as COSV100313943; called by muse, mutect2, varscan2
- THAP10 | c.435G>A p.T145= | Silent (SNP) | VAF 14/53 reads (26%) | catalogued as rs150853216; called by muse, mutect2, varscan2
- TNPO2 | c.1506C>T p.A502= | Silent (SNP) | VAF 21/62 reads (34%) | catalogued as rs770138211; called by muse, mutect2, varscan2
- TRGV2 | c.213C>T p.Y71= | Silent (SNP) | VAF 58/171 reads (34%) | called by muse, mutect2, varscan2
- TTN | c.12078A>G p.E4026= (on ENST00000591111; = p.E3980= on NM_003319.4) | Silent (SNP) | VAF 8/24 reads (33%) | called by muse, mutect2, varscan2
- UNC45B | c.2229C>T p.L743= | Silent (SNP) | VAF 13/57 reads (23%) | called by muse, mutect2, varscan2
- ZKSCAN8 | c.1173A>T p.T391= | Silent (SNP) | VAF 13/37 reads (35%) | called by muse, mutect2, varscan2
- ZMYND8 | c.471G>T p.L157= (on ENST00000311275 / NM_001363741.2; = p.L177= on NM_012408.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 8/74 reads (11%) | called by muse, mutect2
- ZNF540 | c.666A>G p.K222= | Silent (SNP) | VAF 17/52 reads (33%) | catalogued as COSV100329771; called by muse, mutect2, varscan2
- ZNF585B | c.750G>A p.A250= | Silent (SNP) | VAF 16/40 reads (40%) | catalogued as rs144159375; called by muse, mutect2
- ZNF587 | c.690C>T p.H230= | Silent (SNP) | VAF 13/54 reads (24%) | catalogued as rs1237575311; called by muse, mutect2, varscan2
- ZNF675 | c.1326T>C p.H442= | Silent (SNP) | VAF 19/55 reads (35%) | called by muse, mutect2, varscan2
- ZNF772 | c.1299T>C p.P433= | Silent (SNP) | VAF 24/65 reads (37%) | called by muse, mutect2, varscan2
- ATAD3B | c.325-116G>A | Intron (SNP) | VAF 18/64 reads (28%) | catalogued as rs765374341; called by muse, mutect2, varscan2
- CLCN5 | c.17-29030C>G | Intron (SNP) | VAF 4/11 reads (36%) | called by mutect2, varscan2
- DCHS2 | n.2674A>C | RNA (SNP) | VAF 15/43 reads (35%) | catalogued as COSV59735613; called by muse, mutect2, varscan2
- DCHS2 | n.1514A>C | RNA (SNP) | VAF 16/60 reads (27%) | called by muse, mutect2, varscan2
- FOLH1B | n.2006T>G | RNA (SNP) | VAF 17/78 reads (22%) | called by muse, mutect2, varscan2
- TTN | c.10303+2614A>C | Intron (SNP) | VAF 21/47 reads (45%) | called by muse, mutect2, varscan2
